Somatic mutation profile of tumor specimen TCGA-68-7755-01A (aliquot TCGA-68-7755-01A-11D-2122-08) from TCGA case TCGA-68-7755, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 60.1 years (21,936 days).
Specimen TCGA-68-7755-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53d49c69-11a1-4498-b64f-62c20219e7dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-68-7755-10A (Blood Derived Normal), aliquot TCGA-68-7755-10A-01D-2122-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/496a2816-ed69-440a-a1d5-7eab32b8cc31

The open-access MAF lists 321 somatic variants for this specimen: 238 protein-altering or splice-affecting, 72 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 201, Silent 72, Nonsense Mutation 15, Frame Shift Del 11, Intron 5, Splice Site 5, RNA 4, Splice Region 2, 5'UTR 2, Frame Shift Ins 2, In Frame Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K4 | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 111/138 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62254942, COSV62259088; called by muse, mutect2, varscan2
- NFE2L2 | c.101G>C p.R34P | Missense Mutation (SNP) | VAF 40/57 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960096, COSV67960161, COSV67961129; called by muse, mutect2, varscan2
- RHOA | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 60/95 reads (63%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV69041798; called by muse, mutect2, varscan2
- ABCC9 | c.3786G>C p.L1262F | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV99687498, COSV99687546; called by muse, mutect2, varscan2
- AC008676.3 | c.510G>C p.Q170H | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.465); catalogued as rs899613862, COSV100400527; called by muse, mutect2, varscan2
- AC092143.1 | c.2320G>A p.D774N | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.706); catalogued as COSV100206129; called by muse, mutect2, varscan2
- ACSM6 | c.902C>A p.T301N | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as COSV100499051; called by muse, mutect2, varscan2
- ADAM2 | c.1888A>C p.K630Q | Missense Mutation (SNP) | VAF 67/168 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.075); catalogued as COSV99697986; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1853G>C p.R618P | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV54465299, COSV99721497; called by muse, mutect2, varscan2
- ADGRB3 | c.1830T>G p.N610K | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as COSV101002038, COSV65402809; called by muse, mutect2, varscan2
- AGGF1 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV100462308; called by muse, mutect2, varscan2
- AKR1D1 | c.382G>T p.G128* | Nonsense Mutation (SNP) | VAF 29/61 reads (48%) | catalogued as COSV54336356, COSV99653298; called by muse, mutect2, varscan2
- ALG13 | c.2639C>A p.S880Y | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs1556517088, COSV99323160; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALS2 | c.3221G>T p.G1074V | Missense Mutation (SNP) | VAF 66/88 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99970145; called by muse, mutect2, varscan2
- ANO5 | c.1622C>G p.T541R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100202289; called by muse, mutect2, varscan2
- AP002512.3 | c.603G>T p.L201F | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.105); catalogued as COSV54407864; called by muse, mutect2, varscan2
- ATG2A | c.3551T>A p.L1184* | Nonsense Mutation (SNP) | VAF 24/65 reads (37%) | catalogued as COSV101034875; called by muse, mutect2, varscan2
- ATG7 | c.623T>G p.V208G | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.649); catalogued as COSV100608095; called by muse, mutect2, varscan2
- AXDND1 | c.1356G>T p.L452F | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100858717; called by muse, mutect2, varscan2
- BAZ2A | c.4608G>T p.R1536= | Splice Region (SNP) | VAF 61/189 reads (32%) | catalogued as rs761570607, COSV99467932; called by muse, mutect2, varscan2
- BRAF | c.2319G>C p.L773F (on ENST00000288602 / NM_001374244.1; = p.L733F on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/145 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99970586; called by muse, mutect2, varscan2
- BRWD3 | c.2886A>T p.K962N | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.17); catalogued as COSV100956418, COSV100956610; called by muse, mutect2, varscan2
- BUD23 | c.680A>G p.E227G | Missense Mutation (SNP) | VAF 148/198 reads (75%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs1554614503, COSV99736981; called by muse, mutect2, varscan2
- C3orf33 | c.251G>T p.R84L (on ENST00000340171 / NM_001308229.2; = p.R41L on NM_173657.2) | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV100420179; called by muse, mutect2, varscan2
- CACNA1E | c.2771G>T p.R924L | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); catalogued as COSV100701288, COSV100705611; called by muse, mutect2, varscan2
- CAMSAP2 | c.1873G>C p.V625L (on ENST00000236925 / NM_001297707.2; = p.V614L on NM_203459.3) | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.756); catalogued as COSV99374455; called by muse, mutect2, varscan2
- CARD17 | c.5C>A p.A2D | Missense Mutation (SNP) | VAF 72/212 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs780199426, COSV100995303; called by muse, mutect2
- CATSPERB | c.2659C>A p.H887N | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.033); catalogued as COSV99831890; called by muse, mutect2, varscan2
- CCDC149 | c.846T>G p.H282Q | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT tolerated (0.15); PolyPhen benign (0.169); catalogued as COSV100164917; called by muse, mutect2, varscan2
- CD209 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 104/276 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as rs200282091; called by muse, mutect2, varscan2
- CDAN1 | c.1837G>C p.G613R | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV100661459; called by muse, mutect2, varscan2
- CDH11 | c.976G>T p.E326* | Nonsense Mutation (SNP) | VAF 61/181 reads (34%) | catalogued as COSV99217974, COSV99219293; called by muse, mutect2, varscan2
- CHD1 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.052); catalogued as COSV99399994; called by muse, mutect2, varscan2
- CHD2 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as COSV100560935; called by muse, mutect2, varscan2
- CHPF2 | c.556T>A p.Y186N | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99223391, COSV99223406; called by muse, mutect2, varscan2
- COL11A1 | c.2789C>A p.P930H | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV62173116, COSV62192119; called by muse, mutect2, varscan2
- COL11A1 | c.2788C>A p.P930T | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV100618185; called by muse, mutect2, varscan2
- COL20A1 | c.2788C>T p.L930F | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.599); catalogued as rs200320542, COSV100491601; called by muse, mutect2, varscan2
- CPN1 | c.162C>A p.S54R | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100962753; called by muse, mutect2, varscan2
- CPSF1 | c.1879C>T p.R627C | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.709); catalogued as rs782489718; called by muse, mutect2, varscan2
- CR2 | c.2029C>G p.R677G | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.43); catalogued as COSV100889715; called by muse, mutect2, varscan2
- CSF3R | c.1726G>C p.A576P | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as COSV100118319; called by muse, mutect2, varscan2
- CSMD3 | c.2284T>G p.S762A (on ENST00000297405 / NM_001363185.1; = p.S658A on NM_052900.3) | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV99849749; called by muse, mutect2, varscan2
- CST9 | c.46C>G p.L16V | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV100980472, COSV100980502; called by muse, mutect2, varscan2
- CXXC1 | c.1487G>T p.R496L | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as COSV99497377; called by muse, mutect2, varscan2
- CYP51A1 | c.1508G>A p.R503H | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs573070525, COSV50153465; called by muse, mutect2, varscan2
- DGKG | c.1577C>T p.A526V | Missense Mutation (SNP) | VAF 72/104 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99403249, COSV99404551; called by muse, mutect2, varscan2
- DNAH8 | c.7921C>T p.Q2641* | Nonsense Mutation (SNP) | VAF 29/100 reads (29%) | catalogued as COSV100547342; called by muse, mutect2, varscan2
- DNMT3A | c.626G>C p.R209P | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.418); catalogued as COSV53069137, COSV99264918; called by muse, mutect2, varscan2
- DRD1 | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM086309, COSV101192503; called by muse, mutect2, varscan2
- EARS2 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs752779979, COSV101492198, COSV71942930; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EME2 | c.403G>C p.A135P | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as COSV99169830; called by muse, mutect2, varscan2
- EML5 | c.4096G>C p.E1366Q (on ENST00000380664; = p.E1374Q on NM_183387.3) | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.349); catalogued as COSV100716278; called by muse, mutect2, varscan2
- ERBB4 | c.2761T>A p.Y921N | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100728219; called by muse, mutect2, varscan2
- ERICH5 | c.506C>G p.S169C | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1460589527, COSV100582893, COSV59316364; called by muse, mutect2, varscan2
- F13B | c.1475T>C p.L492S | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.878); catalogued as COSV100803506; called by muse, mutect2, varscan2
- FAM71A | c.648G>T p.Q216H | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.808); catalogued as COSV99674441, COSV99674933; called by muse, mutect2, varscan2
- FANCF | c.77G>A p.W26* | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | catalogued as COSV100541910; called by muse, mutect2, varscan2
- FANCL | c.97-1G>T p.X33_splice | Splice Site (SNP) | VAF 18/58 reads (31%) | catalogued as COSV99288018; called by muse, mutect2, varscan2
- FBXO40 | c.273C>A p.S91R | Missense Mutation (SNP) | VAF 52/95 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100573344, COSV57521872, COSV57525984; called by muse, mutect2, varscan2
- FBXW7 | c.1193C>A p.S398Y (on ENST00000281708 / NM_001349798.2; = p.S318Y on NM_018315.5) | Missense Mutation (SNP) | VAF 45/72 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55915633, COSV55933240; called by muse, mutect2, varscan2
- FDXACB1 | c.1648T>C p.F550L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99500390; called by muse, mutect2, varscan2
- FHL5 | c.8C>A p.T3N | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100459857; called by muse, mutect2, varscan2
- FREM2 | c.3268A>G p.I1090V | Missense Mutation (SNP) | VAF 77/111 reads (69%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs201566223, COSV99751300; called by muse, mutect2, varscan2
- GABRA2 | c.758T>A p.F253Y | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100734806; called by muse, mutect2, varscan2
- GCKR | c.992A>C p.Y331S | Missense Mutation (SNP) | VAF 105/306 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.571); catalogued as COSV99269481; called by muse, mutect2, varscan2
- GGA1 | c.1675G>A p.V559M | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.379); catalogued as rs771461283, COSV100289923; called by mutect2, varscan2
- GPR35 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs781464290, COSV60577654; called by muse, mutect2, varscan2
- GUCA1C | c.391C>G p.P131A | Missense Mutation (SNP) | VAF 78/138 reads (57%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as rs529796023, COSV53752203, COSV99660009; called by muse, mutect2, varscan2
- HERC1 | c.4202G>A p.R1401Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.921); catalogued as rs372304757; called by muse, varscan2
- HOXB13 | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 70/130 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV99284995; called by muse, mutect2, varscan2
- HUWE1 | c.12175G>A p.G4059S | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99474555; called by muse, mutect2, varscan2
- IL1RAPL1 | c.327G>T p.L109F | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.038); catalogued as COSV100151098; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1445G>T p.R482L | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100782131; called by muse, mutect2, varscan2
- IPO7 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 51/131 reads (39%) | catalogued as COSV101121854; called by muse, mutect2, varscan2
- IREB2 | c.1231T>C p.Y411H | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144938417; called by muse, mutect2, varscan2
- ITIH2 | c.1108G>C p.V370L | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100623460; called by muse, mutect2, varscan2
- KAT6B | c.5971G>A p.A1991T | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs774281154, COSV99769202; called by muse, mutect2, varscan2
- KATNIP | c.3611C>G p.P1204R | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV99852136; called by muse, mutect2, varscan2
- KCNJ3 | c.1285A>T p.S429C | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.594); catalogued as COSV99716574; called by muse, mutect2, varscan2
- KCNU1 | c.3050T>G p.V1017G | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV101299449, COSV67754643; called by muse, mutect2, varscan2
- KDM5B | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.39); catalogued as COSV99351523; called by muse, mutect2, varscan2
- KIR2DL3 | c.401A>T p.Q134L | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.116); catalogued as COSV100668131; called by muse, mutect2, varscan2
- KLF8 | c.815G>T p.R272L | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100808299; called by muse, mutect2, varscan2
- LAMA2 | c.6974G>T p.C2325F | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101370895; called by muse, mutect2, varscan2
- LHX8 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as rs201945188, COSV99634519; called by muse, mutect2, varscan2
- LRP2 | c.10002C>G p.Y3334* | Nonsense Mutation (SNP) | VAF 42/57 reads (74%) | catalogued as COSV99788937, COSV99790525; called by muse, mutect2, varscan2
- LRRTM4 | c.896C>G p.A299G | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); catalogued as COSV101297751, COSV69141392, COSV69142654; called by muse, mutect2, varscan2
- LUZP2 | c.819G>T p.K273N | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV100421574; called by muse, mutect2, varscan2
- MAGEA11 | c.1119G>T p.Q373H | Missense Mutation (SNP) | VAF 104/180 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV100290742; called by muse, mutect2, varscan2
- MAGEB6 | c.566G>T p.R189L | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100983883, COSV66872315; called by muse, mutect2, varscan2
- MAGEB6 | c.819A>T p.E273D | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.56); catalogued as COSV100983884; called by muse, mutect2, varscan2
- MAGI3 | c.1736T>A p.I579N | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV100290601; called by muse, mutect2, varscan2
- MANF | c.265A>G p.I89V | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV99815542; called by muse, mutect2, varscan2
- MAPT | c.943G>A p.A315T (on ENST00000262410 / NM_001377265.1; = p.A240T on NM_016835.4) | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0.014); catalogued as COSV52238604, COSV99291469; called by muse, mutect2, varscan2
- MDGA2 | c.1549C>A p.Q517K (on ENST00000399232 / NM_001113498.2; = p.Q219K on NM_182830.4) | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100638641; called by muse, mutect2, varscan2
- MED14 | c.3818G>T p.W1273L | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV100247667; called by muse, mutect2, varscan2
- MED14 | c.3596C>T p.A1199V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.444); catalogued as COSV100247668; called by muse, mutect2, varscan2
- MEP1B | c.883C>G p.P295A | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99329183; called by muse, mutect2, varscan2
- METTL25 | c.883A>T p.T295S | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs766710791, COSV99942743; called by muse, mutect2, varscan2
- MIA2 | c.499G>T p.A167S | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99696954; called by muse, mutect2, varscan2
- MKI67 | c.6305C>T p.A2102V | Missense Mutation (SNP) | VAF 152/436 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV100897044; called by muse, varscan2
- MLH3 | c.3812A>G p.Q1271R (on ENST00000355774 / NM_001040108.2; = p.Q1247R on NM_014381.3) | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99470749; called by muse, mutect2, varscan2
- MORC1 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51733042; called by muse, mutect2, varscan2
- MPZL3 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99636594; called by muse, mutect2, varscan2
- MS4A7 | c.553C>A p.L185I | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100279787; called by muse, mutect2, varscan2
- MUC16 | c.6140C>A p.A2047E | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs754984655, COSV101201944; called by muse, mutect2, varscan2
- MYBPC3 | c.2588C>T p.P863L | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99921047; called by muse, mutect2, varscan2
- MYH7 | c.5293A>T p.M1765L | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); catalogued as COSV100806769; called by muse, mutect2, varscan2
- MYH7 | c.5292G>A p.M1764I | Missense Mutation (SNP) | VAF 56/169 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.378); catalogued as COSV100806771; called by muse, mutect2, varscan2
- MZT2A | c.464A>T p.Q155L | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV58312952; called by muse, mutect2, varscan2
- N4BP2L2 | c.2305C>T p.Q769* (on ENST00000674422; = p.Q340* on NM_033111.4) | Nonsense Mutation (SNP) | VAF 7/11 reads (64%) | catalogued as COSV62631424; called by muse, mutect2
- NBAS | c.6827C>T p.T2276M | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.188); catalogued as rs144615326; called by muse, mutect2, varscan2
- NBAS | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV99871905; called by muse, mutect2, varscan2
- NLRP12 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); catalogued as rs200736514, COSV60743990, COSV60753353; called by muse, mutect2, varscan2
- NLRP4 | c.183G>T p.K61N | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100017300; called by muse, mutect2, varscan2
- NMS | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.076); catalogued as rs776719466, COSV100966673; called by muse, mutect2, varscan2
- NOL6 | c.1162A>G p.T388A | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV99955279; called by muse, mutect2, varscan2
- NTM | c.602G>A p.C201Y | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100869673; called by muse, mutect2, varscan2
- OGDHL | c.2794G>T p.E932* | Nonsense Mutation (SNP) | VAF 13/23 reads (57%) | catalogued as COSV100934564; called by muse, mutect2, varscan2
- OR10G4 | c.404T>A p.M135K | Missense Mutation (SNP) | VAF 24/301 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV100305014; called by muse, mutect2
- OR10Q1 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 97/256 reads (38%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV100372418; called by muse, mutect2, varscan2
- OR14J1 | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV101012876; called by muse, mutect2, varscan2
- OR2M3 | c.298C>G p.Q100E | Missense Mutation (SNP) | VAF 60/320 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.323); catalogued as COSV101513534; called by muse, mutect2, varscan2
- OR2T1 | c.403A>T p.M135L | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100822361; called by muse, mutect2, varscan2
- OR4A15 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.009); catalogued as rs767252403, COSV100124387; called by muse, mutect2, varscan2
- OR5B2 | c.788G>T p.S263I | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.397); catalogued as COSV100222890; called by muse, mutect2, varscan2
- OR5D13 | c.321C>A p.C107* | Nonsense Mutation (SNP) | VAF 56/179 reads (31%) | catalogued as rs760709569, COSV62333668; called by muse, mutect2, varscan2
- OR7A17 | c.319T>C p.F107L | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV100541719; called by muse, mutect2, varscan2
- OR8K3 | c.293C>A p.A98E | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV100449682; called by muse, mutect2, varscan2
- OR8K5 | c.908del p.K303Sfs*? | Frame Shift Del (DEL) | VAF 19/63 reads (30%) | catalogued as COSV57890552; called by mutect2, pindel, varscan2
- PAK2 | c.1542G>T p.M514I | Missense Mutation (SNP) | VAF 186/258 reads (72%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100506402; called by muse, mutect2, varscan2
- PAPPA2 | c.1117G>T p.G373* | Nonsense Mutation (SNP) | VAF 16/52 reads (31%) | catalogued as COSV100867223, COSV62778768; called by muse, mutect2, varscan2
- PAX1 | c.1067C>T p.S356F | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.656); catalogued as rs576117670, COSV101270396; called by muse, mutect2, varscan2
- PCDH11X | c.501C>A p.D167E | Missense Mutation (SNP) | VAF 35/52 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100015760; called by muse, mutect2, varscan2
- PCDH11X | c.2474T>G p.V825G | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV100015763; called by muse, mutect2, varscan2
- PCDH15 | c.2320G>T p.A774S | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.1); catalogued as COSV100229911, COSV57285609; called by muse, mutect2, varscan2
- PCDH9 | c.2029T>A p.S677T | Missense Mutation (SNP) | VAF 36/51 reads (71%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as COSV100124042, COSV60601989; called by muse, mutect2, varscan2
- PCDHB8 | c.1526C>G p.T509R | Missense Mutation (SNP) | VAF 68/134 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as COSV99177487; called by muse, mutect2, varscan2
- PCDHGA2 | c.465G>T p.K155N | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.012); catalogued as COSV54013576, COSV99548236; called by muse, mutect2, varscan2
- PCDHGB2 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.474); catalogued as rs1366415460, COSV99548238; called by muse, mutect2, varscan2
- PCLO | c.4359G>C p.Q1453H | Missense Mutation (SNP) | VAF 76/110 reads (69%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100438695; called by muse, mutect2, varscan2
- PDE1C | c.1829G>T p.G610V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.034); catalogued as rs773496943, COSV58511052, COSV58511393; called by muse, mutect2, varscan2
- PGBD5 | c.925C>A p.L309M (on ENST00000525115; = p.L378M on NM_001258311.2) | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV100358943; called by muse, mutect2, varscan2
- PGK2 | c.1052G>T p.G351V | Missense Mutation (SNP) | VAF 62/125 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100505733, COSV59163640; called by muse, mutect2, varscan2
- PIK3R4 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100768619; called by muse, mutect2, varscan2
- PIM2 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99900602; called by muse, mutect2, varscan2
- PIP5K1B | c.1348G>T p.D450Y | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.947); catalogued as COSV99599926; called by muse, mutect2, varscan2
- PKHD1 | c.4051G>T p.G1351* | Nonsense Mutation (SNP) | VAF 22/52 reads (42%) | catalogued as COSV100584778; called by muse, mutect2, varscan2
- PLA2G2E | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.784); catalogued as COSV64290670; called by muse, mutect2, varscan2
- PLCB1 | c.1830G>T p.M610I | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV100572355; called by muse, mutect2, varscan2
- PLCE1 | c.3734A>G p.N1245S | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99597532; called by muse, mutect2, varscan2
- PLEKHA5 | c.1658A>C p.Y553S | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.921); catalogued as COSV100164826; called by muse, mutect2, varscan2
- PLXNA4 | c.4436G>A p.G1479D | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1562891487, COSV100324681, COSV100327629; called by muse, mutect2, varscan2
- PNPLA6 | c.2641del p.D881Tfs*24 (on ENST00000414982 / NM_001166111.2; = p.D833Tfs*24 on NM_006702.5) | Frame Shift Del (DEL) | VAF 24/69 reads (35%) | catalogued as rs780746994; called by mutect2, pindel, varscan2
- POTEF | c.2309C>A p.P770H | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100665414; called by muse, mutect2, varscan2
- PPP1R16B | c.823-1G>A p.X275_splice | Splice Site (SNP) | VAF 37/105 reads (35%) | catalogued as COSV100238943, COSV100240137; called by muse, mutect2, varscan2
- PROS1 | c.1323G>T p.P441= | Splice Region (SNP) | VAF 48/76 reads (63%) | catalogued as COSV67774077; called by muse, mutect2, varscan2
- PTCD1 | c.856A>G p.S286G | Missense Mutation (SNP) | VAF 159/216 reads (74%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs1301716407, COSV99464637; called by muse, mutect2, varscan2
- PTCD3 | c.1648G>T p.D550Y | Missense Mutation (SNP) | VAF 47/199 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99606697; called by muse, mutect2, varscan2
- PTH1R | c.1310G>T p.W437L | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100481201; called by muse, mutect2, varscan2
- PTPRD | c.5540G>C p.G1847A | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100643962, COSV100647403; called by muse, mutect2, varscan2
- PTPRG | c.3833C>T p.T1278I | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV55664162; called by muse, mutect2, varscan2
- PUS7L | c.362A>T p.K121I | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.168); catalogued as COSV100786631; called by muse, mutect2, varscan2
- RAG2 | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 94/272 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57559431; called by muse, mutect2, varscan2
- RGL4 | c.844C>A p.L282I | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99318821; called by muse, mutect2, varscan2
- RHBDL1 | c.733G>T p.A245S (on ENST00000219551 / NM_001318733.2; = p.A180S on NM_001278720.2) | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV99556053; called by muse, mutect2, varscan2
- RHCG | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.2); catalogued as rs368487303; called by muse, mutect2, varscan2
- RICTOR | c.3913G>T p.A1305S | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV99705821; called by muse, mutect2, varscan2
- RPGRIP1L | c.2102A>T p.H701L | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as COSV100046918; called by muse, mutect2, varscan2
- RSF1 | c.1534G>T p.D512Y | Missense Mutation (SNP) | VAF 63/168 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.259); catalogued as COSV100408062; called by muse, mutect2, varscan2
- RTF1 | c.1891G>C p.D631H | Missense Mutation (SNP) | VAF 174/234 reads (74%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.52); catalogued as COSV101048287; called by muse, mutect2
- RYR2 | c.2081G>T p.R694L | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100773177; called by muse, mutect2, varscan2
- SACS | c.10633G>C p.V3545L | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT tolerated (0.28); PolyPhen benign (0.085); catalogued as COSV101207770; called by muse, mutect2, varscan2
- SBF1 | c.4841A>G p.N1614S | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0.435); catalogued as rs773366726, COSV100818074; called by muse, mutect2, varscan2
- SEMA5B | c.3211C>A p.L1071M | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as rs933679820, COSV99533369; called by muse, mutect2, varscan2
- SHROOM3 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768503568, COSV56027817; called by muse, mutect2, varscan2
- SI | c.4861A>T p.T1621S | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV100017387; called by muse, mutect2, varscan2
- SLC18A3 | c.1444C>A p.R482S | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.268); catalogued as rs138708428, COSV100341015; called by muse, mutect2, varscan2
- SLC26A11 | c.588G>T p.E196D | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV100755478; called by muse, mutect2, varscan2
- SLFN12 | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs532166233, COSV100513248; called by muse, mutect2, varscan2
- SLITRK3 | c.1798C>G p.R600G | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.056); catalogued as COSV53846188, COSV99580284; called by muse, mutect2, varscan2
- SPTA1 | c.4475A>T p.E1492V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV100935676; called by muse, mutect2, varscan2
- SUN2 | c.2024A>T p.Q675L | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV99323533; called by muse, mutect2, varscan2
- SYNE1 | c.12099C>A p.H4033Q (on ENST00000367255 / NM_182961.4; = p.H3962Q on NM_033071.3) | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as COSV99581645; called by muse, mutect2, varscan2
- TDRD3 | c.1162A>G p.K388E | Missense Mutation (SNP) | VAF 47/67 reads (70%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.467); catalogued as COSV99541302; called by muse, mutect2, varscan2
- TDRD5 | c.2399G>T p.G800V | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV99677339; called by muse, mutect2, varscan2
- TESPA1 | c.1537C>A p.H513N (on ENST00000316577 / NM_001098815.3; = p.H375N on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 98/256 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.145); catalogued as COSV100345712; called by muse, mutect2, varscan2
- TLN2 | c.1914G>C p.Q638H | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV100170240; called by muse, mutect2, varscan2
- TM2D3 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.029); catalogued as COSV100255067; called by muse, varscan2
- TMEM169 | c.620G>T p.C207F | Missense Mutation (SNP) | VAF 95/141 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99824679; called by muse, mutect2, varscan2
- TMPRSS15 | c.1061G>T p.C354F | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53045331; called by muse, mutect2, varscan2
- TNXB | c.10432A>G p.K3478E (on ENST00000647633; = p.K3231E on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1370169851, COSV100926718; called by muse, mutect2, varscan2
- TP63 | c.26C>A p.A9D | Missense Mutation (SNP) | VAF 245/340 reads (72%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.003); catalogued as COSV99289177; called by muse, mutect2, varscan2
- TRIM22 | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 19/30 reads (63%) | catalogued as COSV101181547; called by muse, mutect2, varscan2
- TTN | c.54306A>C p.K18102N (on ENST00000591111; = p.K10678N on NM_003319.4) | Missense Mutation (SNP) | VAF 53/268 reads (20%) | PolyPhen benign (0.382); catalogued as COSV100633049; called by muse, mutect2, varscan2
- TXLNG | c.175C>G p.Q59E | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV101200613; called by muse, mutect2, varscan2
- UBA3 | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 57/93 reads (61%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV100734795; called by muse, mutect2, varscan2
- UBE2M | c.356G>A p.W119* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as COSV99448402; called by muse, mutect2, varscan2
- UNC13C | c.6289A>C p.K2097Q | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99523614; called by muse, mutect2, varscan2
- UNC5D | c.701C>A p.A234D | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV54818378; called by muse, mutect2, varscan2
- UNC5D | c.2164-1G>A p.X722_splice | Splice Site (SNP) | VAF 47/138 reads (34%) | catalogued as COSV99779233; called by muse, mutect2, varscan2
- USH2A | c.10342G>T p.E3448* | Nonsense Mutation (SNP) | VAF 16/79 reads (20%) | catalogued as CM1312809, COSV100243377; called by muse, mutect2, varscan2
- VIP | c.49A>C p.S17R | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); catalogued as COSV100923972; called by muse, mutect2, varscan2
- WWOX | c.409+2T>C p.X137_splice | Splice Site (SNP) | VAF 11/67 reads (16%) | catalogued as rs1210190094, COSV100880632; called by muse, mutect2, varscan2
- XIRP2 | c.6330T>A p.S2110R (on ENST00000628543; = p.S2285R on NM_152381.6) | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as COSV54710581, COSV99748167; called by muse, mutect2, varscan2
- ZC3H13 | c.2303G>A p.R768Q | Missense Mutation (SNP) | VAF 38/55 reads (69%) | SIFT tolerated, low confidence (0.3); PolyPhen probably damaging (0.968); catalogued as COSV54447944, COSV99669012; called by muse, mutect2, varscan2
- ZFHX4 | c.7699C>G p.H2567D | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.783); catalogued as COSV51502970, COSV99268479; called by muse, mutect2, varscan2
- ZFP1 | c.1213G>C p.E405Q | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV100182174; called by muse, mutect2, varscan2
- ZFP36L1 | c.33C>G p.F11L | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100322530, COSV60544240; called by muse, mutect2
- ZKSCAN3 | c.1108T>C p.Y370H | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99357168; called by muse, mutect2, varscan2
- ZMIZ2 | c.607G>C p.G203R | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV99537280; called by muse, mutect2, varscan2
- ZNF28 | c.1555G>C p.G519R | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.646); catalogued as COSV100354809; called by muse, mutect2, varscan2
- ZNF430 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs886549332, COSV99842087; called by muse, mutect2, varscan2
- ZNF512 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as COSV100821080; called by muse, mutect2, varscan2
- ZNF516 | c.3465G>T p.Q1155H | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101487380; called by muse, mutect2, varscan2
- ZNF587 | c.1684A>T p.T562S | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100299706; called by muse, mutect2, varscan2
- ZNF831 | c.4937T>A p.L1646H | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV100926293; called by muse, mutect2, varscan2
- ZSCAN18 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as rs866086860, COSV53730294; called by muse, mutect2, varscan2
- ANKS4B | c.733dup p.D245Gfs*19 | Frame Shift Ins (INS) | VAF 31/91 reads (34%) | called by mutect2, pindel, varscan2
- BOP1 | c.782A>G p.H261R | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- C17orf75 | c.970_974del p.L324Gfs*24 | Frame Shift Del (DEL) | VAF 24/137 reads (18%) | called by mutect2, pindel
- CNOT10 | c.23-3_40del p.X8_splice | Splice Site (DEL) | VAF 16/32 reads (50%) | called by mutect2, pindel
- CSF2RA | c.1006del p.V337Sfs*30 | Frame Shift Del (DEL) | VAF 136/367 reads (37%) | called by mutect2, pindel, varscan2
- FAT1 | c.11942del p.Y3981Ffs*2 | Frame Shift Del (DEL) | VAF 55/97 reads (57%) | called by mutect2, pindel, varscan2
- GPR137B | c.650_661dup p.S217_S220dup | In Frame Ins (INS) | VAF 24/104 reads (23%) | called by mutect2, varscan2
- IGKV2D-28 | c.7C>G p.L3V | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.022); called by mutect2, varscan2
- IGKV3D-7 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.175); called by muse, mutect2
- KMT2D | c.14811del p.T4938Pfs*57 | Frame Shift Del (DEL) | VAF 23/68 reads (34%) | called by mutect2, pindel, varscan2
- MARCHF6 | c.512del p.G171Efs*88 | Frame Shift Del (DEL) | VAF 33/103 reads (32%) | called by mutect2, pindel, varscan2
- MUC16 | c.42808_42810del p.S14270del | In Frame Del (DEL) | VAF 5/23 reads (22%) | called by pindel, varscan2
- NBPF9 | c.384G>T p.Q128H | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- NFKBIZ | c.1613del p.G538Efs*16 | Frame Shift Del (DEL) | VAF 24/98 reads (24%) | called by mutect2, pindel, varscan2
- OR4F21 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by mutect2, varscan2
- OR5F1 | c.472del p.V158Sfs*37 | Frame Shift Del (DEL) | VAF 33/91 reads (36%) | called by mutect2, pindel, varscan2
- SCN3B | c.373del p.E125Sfs*11 | Frame Shift Del (DEL) | VAF 26/94 reads (28%) | called by mutect2, pindel, varscan2
- SLC45A2 | c.893_894del p.R298Qfs*55 | Frame Shift Del (DEL) | VAF 13/54 reads (24%) | called by mutect2, pindel, varscan2
- ZNF263 | c.1164dup p.N389* | Frame Shift Ins (INS) | VAF 37/141 reads (26%) | called by mutect2, pindel, varscan2
- ABCA13 | c.6159C>T p.Y2053= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV101330197; called by muse, mutect2, varscan2
- ACTN2 | c.771G>A p.A257= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs201545916, COSV100856632, COSV63978506; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AFAP1 | c.1122C>T p.L374= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs1223808824, COSV61798902; called by muse, mutect2, varscan2
- ANKRD27 | c.531A>C p.S177= | Silent (SNP) | VAF 42/148 reads (28%) | catalogued as rs1190957044, COSV100043212; called by muse, mutect2, varscan2
- APC | c.36A>G p.Q12= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs864622288, COSV99970622; ClinVar: likely benign; called by muse, mutect2, varscan2
- AQP3 | c.795C>T p.I265= | Silent (SNP) | VAF 38/128 reads (30%) | catalogued as rs771909436, COSV99955718; called by muse, mutect2, varscan2
- ATM | c.7251G>T p.L2417= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV99592280; called by muse, mutect2, varscan2
- ATP10A | c.3606C>A p.T1202= | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as COSV100791604; called by muse, mutect2, varscan2
- ATP10A | c.1000C>A p.R334= | Silent (SNP) | VAF 42/132 reads (32%) | catalogued as COSV100791605; called by muse, mutect2, varscan2
- BGN | c.10C>T p.L4= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as COSV100525308; called by muse, mutect2, varscan2
- C3 | c.1182G>A p.E394= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV55568366; called by muse, mutect2, varscan2
- CDH9 | c.1827C>T p.A609= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV99159456; called by muse, mutect2, varscan2
- CEP250 | c.1248G>T p.V416= | Silent (SNP) | VAF 36/75 reads (48%) | catalogued as COSV100699236; called by muse, mutect2, varscan2
- CHI3L2 | c.210G>A p.K70= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV100869330, COSV100869334; called by muse, mutect2, varscan2
- CPT1C | c.306G>T p.R102= | Silent (SNP) | VAF 57/108 reads (53%) | catalogued as COSV99773713; called by muse, mutect2, varscan2
- CYBB | c.861G>A p.R287= | Silent (SNP) | VAF 60/268 reads (22%) | catalogued as rs1556469853, COSV101059797, COSV101059834; called by muse, mutect2, varscan2
- CYTIP | c.945C>A p.P315= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as COSV99938955; called by muse, mutect2, varscan2
- DNAH9 | c.5265C>T p.A1755= | Silent (SNP) | VAF 61/83 reads (73%) | catalogued as COSV99308503; called by muse, mutect2, varscan2
- DNM1L | c.69C>T p.I23= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99846501; called by muse, mutect2, varscan2
- DZIP3 | c.2583A>G p.T861= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV100848115; called by muse, mutect2, varscan2
- ECH1 | c.12G>T p.G4= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV99669747; called by muse, mutect2, varscan2
- EGFLAM | c.717T>A p.P239= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV100380869; called by muse, mutect2, varscan2
- EPB41L2 | c.2007A>G p.K669= | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as COSV100441484; called by muse, mutect2, varscan2
- EPHA6 | c.813G>A p.G271= | Silent (SNP) | VAF 127/252 reads (50%) | catalogued as rs975884896, COSV101065911; called by muse, mutect2, varscan2
- ERO1A | c.201A>G p.K67= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV101193690; called by muse, varscan2
- FAM83H | c.2970G>A p.P990= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs1554621828, COSV100568132; called by muse, mutect2
- FCGBP | c.8856C>T p.I2952= | Silent (SNP) | VAF 18/180 reads (10%) | catalogued as rs778664413; called by muse, mutect2
- FGF13 | c.621A>G p.P207= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs774144022, COSV100264662; called by muse, mutect2, varscan2
- FPR3 | c.837C>A p.I279= | Silent (SNP) | VAF 19/127 reads (15%) | catalogued as COSV100200913; called by muse, mutect2, varscan2
- FRMPD2 | c.2751G>T p.V917= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV100564260; called by mutect2, varscan2
- GHR | c.303C>T p.C101= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as CM050055, COSV100052208, COSV50132600; called by muse, varscan2
- GPR31 | c.394C>T p.L132= | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as COSV100834176; called by muse, mutect2, varscan2
- HIC2 | c.51G>C p.G17= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV101335649; called by muse, mutect2, varscan2
- IGKV1-6 | c.136C>A p.R46= | Silent (SNP) | VAF 147/275 reads (53%) | called by muse, mutect2, varscan2
- IPO4 | c.31C>A p.R11= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs542303871, COSV55779868, COSV99938057; called by muse, varscan2
- KCNN3 | c.1359G>A p.T453= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as rs370594487, COSV55227060; called by muse, mutect2, varscan2
- KCNQ2 | c.822G>A p.T274= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs377485599, COSV60434539; called by muse, mutect2, varscan2
- KDM5C | c.4476C>T p.V1492= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as rs1556832388, COSV100949536; called by muse, mutect2, varscan2
- LENG8 | c.2103A>T p.A701= | Silent (SNP) | VAF 38/82 reads (46%) | catalogued as COSV100418236; called by muse, mutect2, varscan2
- MARCHF6 | c.645C>T p.N215= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs779472347, COSV99930217; called by muse, mutect2, varscan2
- MUC16 | c.31254A>T p.S10418= | Silent (SNP) | VAF 77/202 reads (38%) | catalogued as COSV101201943; called by muse, mutect2, varscan2
- NAV3 | c.3492C>A p.S1164= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV99893480; called by muse, mutect2, varscan2
- NBEA | c.1128T>A p.T376= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV100084773; called by muse, mutect2
- NLGN4X | c.1497C>A p.I499= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV99324253; called by muse, mutect2, varscan2
- NUTM2G | c.510G>T p.V170= | Silent (SNP) | VAF 60/135 reads (44%) | catalogued as COSV100672990; called by muse, mutect2, varscan2
- NWD1 | c.3678C>T p.Y1226= | Silent (SNP) | VAF 43/115 reads (37%) | catalogued as rs747397168, COSV60338903; called by muse, mutect2, varscan2
- OR1E1 | c.855G>A p.L285= | Silent (SNP) | VAF 58/88 reads (66%) | catalogued as COSV100492058; called by muse, mutect2, varscan2
- PCM1 | c.2691A>T p.A897= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as COSV100279702; called by muse, mutect2, varscan2
- PDYN | c.669G>A p.Q223= | Silent (SNP) | VAF 66/163 reads (40%) | catalogued as COSV99453401; called by muse, mutect2, varscan2
- PSD4 | c.1969C>A p.R657= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as rs145761056, COSV99831514; called by muse, mutect2, varscan2
- PSG8 | c.6G>T p.G2= | Silent (SNP) | VAF 45/121 reads (37%) | catalogued as COSV100126675; called by muse, mutect2, varscan2
- PTPRB | c.264C>T p.S88= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV99318994; called by muse, mutect2, varscan2
- RBM17 | c.102G>A p.K34= | Silent (SNP) | VAF 46/99 reads (46%) | catalogued as COSV101159184; called by muse, mutect2, varscan2
- RGS18 | c.591C>T p.I197= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV100817916, COSV66507464; called by muse, mutect2, varscan2
- RHBDD1 | c.741G>A p.P247= | Silent (SNP) | VAF 31/61 reads (51%) | catalogued as rs373351039; called by muse, mutect2, varscan2
- SEC11A | c.144G>T p.P48= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs373129075; called by muse, mutect2, varscan2
- SEZ6L | c.1993C>A p.R665= | Silent (SNP) | VAF 50/146 reads (34%) | catalogued as COSV99962199, COSV99963086; called by muse, varscan2
- SHPRH | c.1596G>A p.R532= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as COSV99262780; called by muse, mutect2, varscan2
- SIGLEC8 | c.669C>T p.T223= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV100367423; called by muse, mutect2, varscan2
- SIN3B | c.2073G>T p.L691= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV99932097; called by muse, mutect2, varscan2
- SLC35E4 | c.135C>T p.G45= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV100299330; called by muse, mutect2
- SPATA7 | c.972G>T p.G324= | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as COSV99248477; called by muse, mutect2, varscan2
- STK4 | c.1323G>T p.V441= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as COSV100860512; called by muse, mutect2, varscan2
- SV2A | c.402G>T p.G134= | Silent (SNP) | VAF 68/128 reads (53%) | catalogued as COSV100975215, COSV64964352; called by muse, mutect2, varscan2
- TMEM248 | c.225C>G p.L75= | Silent (SNP) | VAF 193/254 reads (76%) | catalogued as rs756827256, COSV100447511; called by muse, mutect2, varscan2
- TTN | c.16177C>A p.R5393= (on ENST00000591111; = p.R4466= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 103/129 reads (80%) | catalogued as COSV100633051; called by muse, mutect2, varscan2
- UGT1A6 | c.171A>G p.V57= | Silent (SNP) | VAF 34/60 reads (57%) | catalogued as COSV100531181; called by muse, mutect2, varscan2
- USP9X | c.1506G>A p.V502= | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as COSV100200196; called by muse, mutect2, varscan2
- VTI1B | c.276T>C p.H92= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as COSV99373882; called by muse, mutect2, varscan2
- YPEL5 | c.126A>T p.A42= | Silent (SNP) | VAF 27/140 reads (19%) | catalogued as COSV99745362; called by muse, mutect2, varscan2
- ZNF513 | c.795T>C p.P265= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs746588960, COSV99278083; called by muse, mutect2, varscan2
- ZNF608 | c.1389G>A p.G463= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as rs746975109, COSV100102535; called by muse, mutect2, varscan2
- ABCA3 | c.-162del | 5'UTR (DEL) | VAF 5/9 reads (56%) | called by mutect2, varscan2
- AC024598.1 | c.1130-1500C>A | Intron (SNP) | VAF 24/100 reads (24%) | catalogued as COSV100760506; called by muse, mutect2, varscan2
- AC244258.1 | n.920G>T | RNA (SNP) | VAF 45/127 reads (35%) | called by muse, mutect2, varscan2
- AL136982.4 | n.273C>A | RNA (SNP) | VAF 81/160 reads (51%) | called by muse, mutect2, varscan2
- ARHGAP28 | c.2030+1936C>T | Intron (SNP) | VAF 12/136 reads (9%) | catalogued as rs1431321338, COSV99151578; called by muse, mutect2
- LIMK2 | c.1773-1454A>T | Intron (SNP) | VAF 12/26 reads (46%) | catalogued as COSV99314264; called by muse, mutect2, varscan2
- MTAP | c.-1C>A | 5'UTR (SNP) | VAF 13/17 reads (76%) | catalogued as COSV101205524; called by muse, mutect2, varscan2
- NR5A2 | c.65-900C>T | Intron (SNP) | VAF 11/43 reads (26%) | catalogued as COSV52649306; called by muse, mutect2, varscan2
- PIGQ | c.1532-604G>T | Intron (SNP) | VAF 11/22 reads (50%) | catalogued as COSV99216609; called by muse, mutect2, varscan2
- SNORD115-44 | n.52A>C | RNA (SNP) | VAF 77/409 reads (19%) | called by muse, mutect2, varscan2
- SSPOP | n.14634A>T | RNA (SNP) | VAF 5/41 reads (12%) | catalogued as COSV100948151; called by muse, mutect2, varscan2
